Surgical pathology report (de-identified scan), TCGA case TCGA-H9-A6BX, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - IUPUI, specimen TCGA-H9-A6BX-01A (Primary Tumor).

[page 1 of 2]
Operative Procedure:
Da Vinci prostatectomy

Specimen Received:
Prostate, resection

Final Pathologic Diagnosis:

Prostate, da Vinci prostatectomy:

Histologic type: Adenocarcinoma

Variant histology present: No

Prostate size: 4 x 4.6 x 3.9 cm; weight: 47 grams

Gleason score (primary + secondary): 3 + 3 = 6

Primary pattern (%): 100%

Secondary pattern (%): Not applicable

Tertiary pattern (%): Not applicable

Tumor quantitation:

Largest tumor focus: 21 mm (greatest dimension)

Additional dimensions: 16 x 8 mm

Location: Right posterior lobe

Multifocality: Yes

Second largest focus: 15 mm (greatest dimension)

Location: Left posterior lobe

Extraprostatic extension: No

Seminal vesicle invasion: No

Cancer at surgical margin: No

If no, closest distance with location: Tumor is <1 mm from the right side margin

Incised specimen: No

Apex involvement: No

Bladder neck involvement: No

Lymph-vascular invasion: No

Perineural invasion: No

Treatment effect on carcinoma: No

Other histologic findings: Nodular hyperplasia of glands and stroma

Lymph nodes sampling: No

Ancillary studies: No

Pathologic stage (2010) pT2c pNX pM not applicable (no information)

The examination of this case material and the preparation of this report were performed by the staff pathologist.

ICD-O-3
Adenocarcinoma, acinar
8140/3
Adenocarcinoma NOS
8140/3
Site Prostate NOS
C61.9
JW 5/24/13

Prior Pathology History		
Case In (title)		

JW 5/10/13 3+3=6
5/21/13

[page 2 of 2]
Gross Description:

Received in formalin, labeled "prostate and seminal vesicles" is a 47 g, 4.0 cm in length by 4.6 cm from right to left by 3.9 cm from anterior to posterior prostate gland with attached bilateral seminal vesicles and segments of vas deferens. The tan-pink, focally cauterized external surface is inked as follows: right yellow, left black, posterior red. The base and apex margins are coned and step-sectioned. Sectioning reveals a tan-pink, heterogeneous, focally cystic parenchyma with minimal periurethral nodularity. No definitive tumor is identified.

Representative sections are submitted as follows:

- 1 apex margin;
- 2 base margin;
- 3-11 right posterior prostate sequentially from apex to base, entirely submitted;
- 12-21 left posterior prostate sequentially from apex to base, entirely submitted;
- 22 right anterior prostate, cross-section two;
- 23 left anterior prostate, cross-section three;
- 24 right anterior prostate, cross-section four;
- 25 left anterior prostate, cross-section five;
- 26 junction of right seminal vesicle and prostate gland;
- 27-28 right seminal vesicle sequentially from proximal to distal;
- 29 junction of left seminal vesicle and prostate gland;
- 30-31 left seminal vesicle sequentially from proximal to distal.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Gender: M

Source: NCI Genomic Data Commons file a8dd102f-2518-412e-a10e-81d90ffe4663 (TCGA-H9-A6BX.5AEA61BF-A79E-4A8A-B3F1-45982DAF288E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).